Somatic mutation profile of tumor specimen TCGA-ZF-AA56-01A (aliquot TCGA-ZF-AA56-01A-31D-A391-08) from TCGA case TCGA-ZF-AA56, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 79.2 years (28,937 days).
Specimen TCGA-ZF-AA56-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7536bcbc-50f3-4e41-b8d8-a29f12a609b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA56-10A (Blood Derived Normal), aliquot TCGA-ZF-AA56-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a8b9021-c8a5-4c42-b3f4-110a2d61bbfc

The open-access MAF lists 104 somatic variants for this specimen: 84 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 17, Nonsense Mutation 4, Frame Shift Ins 3, Splice Site 3, Intron 2, Splice Region 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTB | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.822); catalogued as rs281875333, CM122511, COSV59317670; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 38/77 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.1657C>G p.Q553E (on ENST00000373394 / NM_001271696.3; = p.Q554E on NM_004299.6) | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53719626; called by muse, mutect2, varscan2
- ADAM21 | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV50792092, COSV50792242; called by muse, mutect2, varscan2
- AGO1 | c.1521G>C p.K507N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV64595165; called by muse, mutect2, varscan2
- ALDH1L2 | c.2585G>C p.R862T | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV51555473; called by muse, mutect2, varscan2
- ARPP21 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV51797018; called by muse, mutect2, varscan2
- ATAD2 | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.09); catalogued as COSV54880351, COSV54883968, COSV54887139; called by muse, mutect2, varscan2
- ATL1 | c.1618C>G p.Q540E | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.006); catalogued as COSV61204812; called by muse, mutect2, varscan2
- B4GALNT2 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs145043273; called by muse, mutect2, varscan2
- C3 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as rs147549358, COSV55572426; called by muse, mutect2, varscan2
- C9orf50 | c.682C>G p.H228D | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.352); catalogued as COSV100992344, COSV65252381; called by muse, mutect2, varscan2
- CASP5 | c.300G>C p.K100N | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV52828427, COSV52829372; called by muse, mutect2, varscan2
- CCL2 | c.131C>G p.S44* | Nonsense Mutation (SNP) | VAF 22/109 reads (20%) | catalogued as COSV99861520; called by muse, mutect2, varscan2
- CD274 | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67500970, COSV67501251; called by muse, mutect2, varscan2
- CDH26 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs925659182, COSV54846414; called by muse, mutect2, varscan2
- CHD3 | c.5363T>A p.M1788K (on ENST00000330494 / NM_001005273.3; = p.M1754K on NM_005852.4) | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV57874720; called by muse, mutect2, varscan2
- CLIP2 | c.1878G>T p.K626N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV56278046; called by muse, mutect2, varscan2
- CNTNAP2 | c.3945C>A p.D1315E | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.022); catalogued as COSV62175424; called by muse, mutect2, varscan2
- CYGB | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV53150152; called by muse, mutect2, varscan2
- DNM1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57851194; called by muse, mutect2
- F13B | c.264C>T p.F88= | Splice Region (SNP) | VAF 21/155 reads (14%) | catalogued as COSV66373683; called by muse, mutect2, varscan2
- F9 | c.18G>A p.M6I | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV54380054; called by muse, mutect2, varscan2
- GLS | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV57841426; called by muse, mutect2, varscan2
- H2BC3 | c.13T>A p.S5T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV100778281, COSV63551413; called by muse, mutect2
- HUWE1 | c.3550G>C p.E1184Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as COSV53344048; called by muse, mutect2, varscan2
- IL18RAP | c.1045T>C p.S349P | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV51825707; called by muse, mutect2, varscan2
- IQCC | c.11A>T p.E4V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV99356519; called by muse, mutect2
- JARID2 | c.224C>G p.S75* | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | catalogued as COSV100521419, COSV100521752; called by muse, mutect2, varscan2
- JDP2 | c.104T>G p.L35R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50867861; called by muse, mutect2, varscan2
- KCTD21 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60740987; called by muse, mutect2, varscan2
- MAP3K9 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.263); catalogued as COSV67121133; called by muse, mutect2, varscan2
- MAT2B | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.188); catalogued as COSV55200678; called by muse, mutect2, varscan2
- MDN1 | c.3757C>A p.L1253I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65521063; called by muse, mutect2, varscan2
- MEP1A | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | catalogued as COSV100042629; called by muse, mutect2, varscan2
- MEP1B | c.1499C>A p.T500K | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV52497306; called by muse, mutect2
- MIS18BP1 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs774444888, COSV60370659; called by muse, mutect2, varscan2
- NEB | c.19460G>A p.R6487Q | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs886054926, COSV51309122; ClinVar: uncertain significance; called by muse, mutect2
- NELL2 | c.1628G>T p.C543F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV61573960, COSV61584919; called by muse, mutect2, varscan2
- NLRP5 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as rs771396943, COSV66762329; called by muse, mutect2, varscan2
- NOSIP | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.116); catalogued as rs1442609579, COSV59198739; called by muse, mutect2, varscan2
- NPAS2 | c.930G>T p.K310N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59557457; called by muse, mutect2
- NRM | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.425); catalogued as COSV51295780; called by muse, mutect2, varscan2
- OR4C6 | c.441G>A p.W147* | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as COSV100051592; called by muse, mutect2, varscan2
- PDK3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100998212, COSV64793361; called by muse, mutect2, varscan2
- PDS5B | c.1400A>C p.N467T | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV59726564; called by muse, mutect2, varscan2
- PLAT | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs944715247, COSV54274513; called by muse, mutect2, varscan2
- PLEC | c.3409G>A p.E1137K (on ENST00000322810 / NM_201380.4; = p.E1027K on NM_000445.5) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59632331; called by muse, mutect2, varscan2
- POLR1A | c.2688G>T p.M896I | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV55692429; called by muse, mutect2, varscan2
- PPIP5K1 | c.4255G>A p.E1419K (on ENST00000396923; = p.E1394K on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55808259; called by muse, mutect2, varscan2
- PPIP5K1 | c.3694G>C p.E1232Q (on ENST00000396923; = p.E1207Q on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.036); catalogued as rs1443722849, COSV55808268; called by muse, mutect2, varscan2
- PRDM2 | c.4801G>A p.A1601T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV52445946; called by muse, mutect2, varscan2
- PRX | c.2536C>T p.H846Y | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs765595266, COSV52529634; ClinVar: uncertain significance; called by muse, mutect2
- RIT2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100451972, COSV58664716; called by muse, mutect2, varscan2
- RNF213 | c.15058G>A p.D5020N | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs151136922, COSV60395628; called by muse, mutect2, varscan2
- SEC31A | c.2337C>G p.I779M (on ENST00000355196 / NM_001318120.1; = p.I740M on NM_016211.4) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV52345004, COSV52352723; called by muse, mutect2, varscan2
- SEMA3E | c.1466T>A p.V489D | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1262061378, COSV57088435; called by muse, mutect2, varscan2
- SETD2 | c.6784C>T p.P2262S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57436817; called by muse, mutect2, varscan2
- SGK1 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.983); catalogued as COSV63116165; called by muse, mutect2, varscan2
- SOS1 | c.2554G>T p.V852L | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1429582356, COSV67675056; called by muse, mutect2
- SP100 | c.2466G>C p.L822F | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60844288; called by muse, mutect2, varscan2
- SPARCL1 | c.1818-1G>C p.X606_splice | Splice Site (SNP) | VAF 8/49 reads (16%) | catalogued as COSV56803382; called by muse, mutect2, varscan2
- STK11IP | c.1331T>G p.L444R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV55248491; called by muse, mutect2, varscan2
- STK32B | c.876C>A p.F292L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51484622; called by muse, mutect2
- SUCO | c.3645G>T p.L1215F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.124); catalogued as COSV55264675; called by muse, mutect2, varscan2
- SUFU | c.1401G>C p.K467N | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as COSV100883357, COSV64017787; called by muse, mutect2, varscan2
- TAAR6 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1234419077, COSV51583411; called by muse, mutect2, varscan2
- TAOK1 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV55591240, COSV55599994; called by muse, mutect2, varscan2
- THBS4 | c.2390G>A p.G797D | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771836899, COSV63469177; called by muse, mutect2, varscan2
- TNIP3 | c.67-2A>G p.X23_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | catalogued as COSV50247453; called by mutect2, varscan2
- TRHR | c.598T>C p.Y200H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61234023; called by muse, mutect2, varscan2
- TULP1 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as COSV57692530; called by muse, mutect2, varscan2
- TXNIP | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as COSV65220406, COSV65220753; called by muse, mutect2
- UBQLN1 | c.1106-1G>C p.X369_splice | Splice Site (SNP) | VAF 14/46 reads (30%) | catalogued as COSV57407888; called by muse, mutect2, varscan2
- WASHC4 | c.3028C>A p.L1010I | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59889393; called by muse, varscan2
- WDFY3 | c.7306G>C p.D2436H | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); catalogued as COSV55699948; called by muse, mutect2, varscan2
- YLPM1 | c.5729G>A p.R1910H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs1339078606, COSV53110874; called by muse, mutect2, varscan2
- ZHX2 | c.1912G>C p.E638Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV58712825; called by muse, mutect2, varscan2
- ZNF14 | c.557G>C p.R186T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.023); catalogued as COSV59849350; called by muse, mutect2, varscan2
- ZNF311 | c.1528G>C p.D510H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.048); catalogued as COSV65852850, COSV65853085; called by muse, mutect2, varscan2
- ELF3 | c.451dup p.Q151Pfs*10 | Frame Shift Ins (INS) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- FAAP100 | c.1669_1679dup p.C560Wfs*25 | Frame Shift Ins (INS) | VAF 20/67 reads (30%) | called by mutect2, varscan2
- KDM6A | c.3876dup p.K1293* | Frame Shift Ins (INS) | VAF 14/109 reads (13%) | called by mutect2, pindel, varscan2
- TP53 | c.44_50del p.S15Kfs*27 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- ADAM11 | c.309G>A p.L103= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV52346040; called by muse, mutect2
- ADAMTS20 | c.2370A>G p.Q790= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV101166210; called by muse, mutect2
- ANXA2 | c.510G>A p.L170= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV60316638; called by muse, mutect2, varscan2
- AXIN2 | c.528C>T p.T176= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs781572220, COSV61057361; called by muse, mutect2, varscan2
- C3 | c.186C>T p.F62= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV55572439; called by muse, mutect2
- CFAP251 | c.3225C>T p.L1075= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs763677936, COSV99996015; called by muse, mutect2
- CYP2A13 | c.1183C>T p.L395= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV57836627, COSV57837507; called by muse, mutect2, varscan2
- DHRSX | c.348C>T p.F116= | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as COSV58133077, COSV58138640; called by muse, mutect2, varscan2
- DYRK4 | c.1446G>A p.L482= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV50539047, COSV99155260; called by muse, mutect2, varscan2
- FNDC4 | c.462C>T p.I154= | Silent (SNP) | VAF 38/175 reads (22%) | catalogued as COSV53021151; called by muse, mutect2, varscan2
- IFI6 | c.321C>T p.V107= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV59269380; called by muse, mutect2, varscan2
- KAT2B | c.1209T>G p.L403= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV55428956; called by muse, mutect2, varscan2
- LCA5L | c.1908C>T p.P636= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV55745003, COSV55747003; called by muse, mutect2, varscan2
- OR56B1 | c.106C>T p.L36= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs758108750, COSV57722812; called by muse, mutect2, varscan2
- PLCE1 | c.219C>G p.L73= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV53348876; called by muse, mutect2, varscan2
- RBBP4 | c.591A>C p.S197= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV65132525; called by muse, mutect2, varscan2
- SEMA4G | c.1569C>G p.P523= | Silent (SNP) | VAF 21/171 reads (12%) | catalogued as COSV52967886, COSV52972162; called by muse, mutect2, varscan2
- CSH2 | c.456+32G>C | Intron (SNP) | VAF 12/142 reads (8%) | catalogued as COSV61080395; called by muse, mutect2
- MACF1 | c.15832-9826G>C | Intron (SNP) | VAF 8/67 reads (12%) | catalogued as COSV57119371; called by muse, mutect2, varscan2
- OR4C3 | c.-15G>T | 5'UTR (SNP) | VAF 14/132 reads (11%) | catalogued as COSV60585653; called by muse, mutect2
